Surgical pathology report (de-identified scan), TCGA case TCGA-02-2466, project TCGA-GBM (Glioblastoma Multiforme), tissue source site MD Anderson Cancer Center, specimen TCGA-02-2466-01A (Primary Tumor).

TCGA-02-2466

DIAGNOSIS

- (A) BRAIN, "LEFT TEMPORAL LOBE":
RECURRENT/RESIDUAL GLIOBLASTOMA (WHO GRADE 4). (SEE COMMENT)
- (B) BRAIN, "LEFT TEMPORAL MASS":
RECURRENT/RESIDUAL GLIOBLASTOMA (WHO GRADE 4) AND NECROSIS. (SEE COMMENT)

COMMENT

The patient has had prior surgery for glioblastoma

GROSS DESCRIPTION

(A) "LEFT TEMPORAL LOBE" - Consists of multiple soft beige fragments together measuring 1.5 x 1.5 x 1.0 cm. Two touch preps are made and representative frozen section labeled A1. The touch preps and the frozen section are used together to formulate the frozen section diagnosis. A portion is labeled A2 for permanent section and the remainder is submitted to Dr.

lab for research. Jar 0.

/DX: A1. RECURRENT/RESIDUAL GLIOBLASTOMA. THE PATIENT HAS HAD PRIOR THERAPY FOR GLIOBLASTOMA

(B) "LEFT TEMPORAL MASS" - Consists of two fragments of beige white tissue measuring 0.5 x 0.5 x 0.2 cm. Labeled B for frozen section. Two touch preps are made and are used in conjunction with the frozen section to formulate the frozen section diagnosis. Jar 0.

/DX: INFILTRATING HIGH-GRADE GLIOMA AND NECROSIS.

CLINICAL HISTORY

Left temporal mass.

SNOMED CODES

T-A2000, M-94403

"Some tests reported here may have been developed and performance characteristics determined by

These tests have not been specifically cleared or

approved by the U.S. Food and Drug Administration."

Source: NCI Genomic Data Commons file 6f601ff4-dff1-414a-89df-ed2d64918748 (TCGA-02-2466.E9E97B51-1474-463B-8693-7B66F74319C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).